Gene-level copy-number profile of tumor specimen TCGA-IQ-7630-01A from TCGA case TCGA-IQ-7630, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.6 years (18,131 days).
Specimen TCGA-IQ-7630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3b9178e7-4a7c-48e8-90ad-d66ef5aea563.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IQ-7630-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5a03d51-a98e-46f9-a9aa-6ebf49854bc9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 8,438; copy number 2: 43,024; copy number 3: 7,099; copy number 4: 252; copy number 5: 606; copy number 7: 76; copy number 10: 59; copy number 11: 118; copy number 17: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IQ-7630-01A-11D-2077-01): tumor purity 0.58, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,560,087–51,643,939, 18 genes: MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9.
- chr18:59,081,911–66,946,222, 101 genes (broad region; genes not listed).
- chr18:67,788,268–67,956,426, 4 genes: AC114689.1, LINC01903, AC114689.2, AC100844.1.
- chr18:73,151,241–74,034,161, 7 genes: LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–1): PARD6G.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 871 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–35,814,611, 541 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:35,038,625–36,677,683, 71 genes, copy number 10–17 (broad region; genes not listed).
- chr9:124,517,275–126,159,613, 34 genes, copy number 5 (within-gene range 1–5): NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP, AL359632.1, MAPKAP1, RN7SL30P, AL162584.1, HNRNPA1P15, AL358074.1, PBX3, AL589923.1.
- chr18:27,225,742–31,162,856, 31 genes, copy number 5: LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1.
- chr20:10,006,381–10,368,776, 1 gene, copy number 11 (within-gene range 1–11): SNAP25-AS1.
- chr20:10,172,522–21,970,783, 193 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,052. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
